Somatic mutation profile of tumor specimen TCGA-ET-A25G-01A (aliquot TCGA-ET-A25G-01A-11D-A16O-08) from TCGA case TCGA-ET-A25G, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 57.0 years (20,816 days).
Specimen TCGA-ET-A25G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c681445e-4463-4273-a0f2-e90f210e428d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A25G-10A (Blood Derived Normal), aliquot TCGA-ET-A25G-10A-01D-A16O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bea16df-8420-41dd-b8b1-94a0dac91ddf

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ARHGAP18 | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV63764435; called by muse, mutect2, varscan2
- COL6A2 | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56004764; called by muse, mutect2, varscan2
- JHY | c.1313C>T p.T438I | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as COSV57075017; called by muse, mutect2, varscan2
- MPDZ | c.1184T>C p.I395T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.207); catalogued as COSV59941250; called by muse, mutect2, varscan2
- PABPC3 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.536); catalogued as COSV55800678; called by muse, mutect2, varscan2
- ZSCAN20 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV63682673; called by muse, mutect2, varscan2
- CLCA1 | c.1521C>T p.I507= | Silent (SNP) | VAF 9/111 reads (8%) | catalogued as COSV52327770; called by muse, mutect2
- ZMIZ2 | c.2136C>G p.L712= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV54808197; called by muse, mutect2, varscan2
- HIGD1A | c.-23+263G>A | Intron (SNP) | VAF 54/190 reads (28%) | catalogued as COSV58414919; called by muse, mutect2, varscan2
- MIR1275 | n.37G>A | RNA (SNP) | VAF 28/78 reads (36%) | called by muse, mutect2, varscan2
